Somatic mutation profile of tumor specimen TCGA-AB-2814-03B (aliquot TCGA-AB-2814-03B-01W-0728-08) from TCGA case TCGA-AB-2814, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.5 years (14,427 days).
Specimen TCGA-AB-2814-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1eae0adb-49e2-4723-864c-5b4a5e6c94dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2814-11B (Solid Tissue Normal), aliquot TCGA-AB-2814-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ef844e0-04cc-493f-ae78-0988971de82d

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 5, Silent 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 250/265 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772832052, COSV58676330; called by muse, mutect2, varscan2
- HMCN1 | c.9290G>A p.G3097E | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54876119; called by muse, mutect2
- NHS | c.1688T>A p.L563Q | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101197028, COSV66271155; called by muse, varscan2
- STAMBPL1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV64222159; called by muse, mutect2
- TREM1 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF574 | c.1352_1353insA p.V452Cfs*3 | Frame Shift Ins (INS) | VAF 12/29 reads (41%) | called by mutect2, varscan2
- ABHD12B | c.984G>A p.R328= (on ENST00000337334 / NM_001206673.2; = p.R251= on NM_181533.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53584164; called by muse, mutect2, varscan2
- IL6 | c.336G>A p.L112= | Silent (SNP) | VAF 76/125 reads (61%) | catalogued as rs780638841, COSV51732234; called by muse, mutect2, varscan2
- LTBP1 | c.4335G>A p.R1445= (on ENST00000404816 / NM_206943.4; = p.R1119= on NM_000627.4) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1446701140, COSV55375388; called by muse, mutect2, varscan2
- NDUFS8 | c.435C>T p.I145= | Silent (SNP) | VAF 43/54 reads (80%) | catalogued as rs565881945, COSV55835600; called by muse, varscan2
- PDE9A | c.822C>T p.C274= | Silent (SNP) | VAF 32/708 reads (5%) | catalogued as COSV99372264; called by muse, mutect2
